Surgical pathology report (de-identified scan), TCGA case TCGA-FB-A4P5, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Asterand, specimen TCGA-FB-A4P5-01A (Primary Tumor).

Procurement Date Laterality: Procedure: Pancreaticoduodenectomy (partial pancreatectomy)

Tumor location: Head

Tumor size (greatest dimension): 4.5 cm

Histologic type: Ductal adenocarcinoma

Histologic g grade: Moderately differentiated (50-95%)

Microscopic tumor extension: Invades peripancreatic soft tissue.

Surgical margins:

Distal: Free of neoplasm

Common bile duct margin: Free of neoplasm

Distal stomach/duodenum margin: Free of neoplasm

Retroperitoneal margins:

Uncinate groove: Involved by neoplasm

Angiolymphatic spread: Yes

Perineural spread: Yes

Treatment effect: No prior treatment

TNM staging:

Tumor extent (Pt3): Invasion beyond pancreas to peripancreatic adipose tissue.

Lymph nodes (pN1):

Peripancreatic, superior: 1 of 4 contain metastases

Peripancreatic, inferior: 0 of 10 contain metastases

Pancreaticoduodenal, anterior: 0 of 3 contain metastases

Pancreaticoduodenal, posterior: 2 of 10 contain metastases

Hepatic artery lymph node (B): 0 of 1 contain metastases

Peripancreatic lymph node (D): 1 of 1 contain metastases

100-0-3

Adenocarcinoma, duct 8500/3

Site: pancreas head C25.0

hw
10/5/12

Peripancreatic lymph node (D): 1 of 1 contain metastases

Source: NCI Genomic Data Commons file f3318bc7-a268-44d0-8cea-75eb772eaa7b (TCGA-FB-A4P5.4A47BFA2-CCFC-4E70-9631-88D856526B08.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).